Surgical pathology report (de-identified scan), TCGA case TCGA-HZ-A77P, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HZ-A77P-01A (Primary Tumor).

[page 1 of 4]
Patient:

Referring Physician:

DOB: Age: Gender: M

Ref#: Hosp#: Provider Group:

Date of Service: Date Received:

Case #

Date Reported:

A copy of this report will be faxed to:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

- A. GALLBLADDER, CHOLECYSTECTOMY:
- MILD CHRONIC CHOLECYSTITIS.
- ONE REACTIVE LYMPH NODE, NO TUMOR SEEN (0/1).
- B. LYMPH NODE, BILE DUCT, EXCISION:
- ONE LYMPH NODE, NO TUMOR SEEN (0/1).
- C. STOMACH, DUODENUM, PANCREAS, WHIPPLE PROCEDURE:
- ADENOCARCINOMA, WELL DIFFERENTIATED.
- TUMOR SIZE 3.1 CM.
- TUMOR INVADES TO PERIPANCREATIC SOFT TISSUE AND INTO MUSCULARIS PROPRIA OF DUODENUM.
- SURGICAL MARGINS NEGATIVE.
- ONE OF TWENTY LYMPH NODES POSITIVE FOR METASTATIC CARCINOMA (1/20).
- LYMPHOVASCULAR INVASION PRESENT.

PATHOLOGIC TUMOR STAGING SYNOPSIS (PANCREAS):

Type and grade: Adenocarcinoma, well differentiated.

Primary tumor: pT3.

Regional lymph node: pN1.

Distant metastasis: N/A.

Pathologic stage: IIB.

Lymphovascular invasion: Present.

Margin status: R0, negative.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging

*ICD-O-3
Adenocarcinoma NOS
8140/3
Site: Pancreas head
C25.0
QW 8/19/13*

[page 2 of 4]
FINAL SURGICAL PATHOLOGY REPORT

Handbook, 7th Ed, and CAP protocol, June 2012.

Specimen:	Stomach, duodenum, pancreas.
Procedure:	Whipple excision.
Tumor site:	Head of pancreas.
Tumor size:	3.1 cm.
Histologic type:	Adenocarcinoma.
Histologic grade:	G1, well differentiated.
Microscopic tumor extension:	Tumor extends to peripancreatic soft tissue and muscularis propria of duodenum.
MARGINS:	 R0, negative, closest margin deep at 0.5 cm, common bile duct and pancreatic margin >2 cm.
Treatment effect:	 N/A.
Lymphovascular invasion:	Present.
Perineural invasion:	Not identified.
LYMPH NODES:	 One of twenty lymph nodes positive for carcinoma (1/20).
PATHOLOGIC TUMOR STAGING:	
Primary tumor:	pT3.
Regional lymph node:	pN1.
Distant metastasis:	N/A.
Pathologic stage:	IIIB.

Source of Specimen:

- A. Gallbladder
- B. Lymph node; Common bile duct lymph node
- C. Whipple

Clinical History/Operative Dx:

Malignant neoplasm of pancreas.

Intraoperative Diagnosis:

██████████ Pancreatic margin - no tumor seen; bile duct - no bile duct tissue identified in frozen section. ██████████

The intraoperative interpretation(s) was/were performed and rendered at ██████████
██████████

Gross Description:

A. Part A designated gallbladder. Received in formalin is a previously disrupted, deflated gallbladder, 7.8 x 3.2 x 1.2 cm. The serosa is glistening, fatty pink and tan. There are two paracystic duct lymph node candidates are 0.3 and 0.4 cm each. The cystic duct margin demonstrates a narrow 1 mm lumen, difficult to probe for patency, however, upon sectioning does not appear obstructed. The lumen contains a residual amount of viscous dark green bile without calculi; no calculi are present within the container. The mucosa is velvety, dark green with few raised yellow flecks without grossly unusual areas of change suggestive of neoplasia. Representative sections are submitted for microscopic evaluation, including representation of the cystic duct margin (orange), lymph node, mid fundus and dome of fundus in A1. ██████████

B. Part B designated common bile duct lymph node. Received in formalin is a rubbery pink and tan lymph node candidate measuring 1.1 x 0.6 x 0.5 cm. The lymph node and surrounding fat is now bisected and submitted together in B1. ██████████

[page 3 of 4]
C. Part C designated Whipple procedure. Initially received in a fresh state for frozen section analysis is a generous portion of tissue, consistent with a Whipple procedure specimen. It consists of a distal portion of the antrum of the stomach, 12.0 cm along the greater curvature and 7.8 cm on the lesser, and up to 7.0 cm in diameter at the proximal surgical margin of resection; the small bowel is 21.0 cm in length with an average diameter of 2.5 cm and up to 3.1 cm at the proximity of the pancreatic head; the pancreas includes the head and portion of the body 5.7 cm in length, 5.0 cm inferior-superior, 4.2 cm anterior-posterior. The common bile duct is obscured by peripancreatic fat, and extends out to 1.8 cm, is markedly narrow, 0.35 cm diameter. The CBD probe patent to a depth of 2.5 cm.

FINAL SURGICAL PATHOLOGY REPORT

The gastric and small bowel is now opened, and examination of the small bowel demonstrates prominent, semi-congested pink and tan circular plicae, with the apparent ampulla of Vater oriented 6.4 cm distal to the pylorus, and is obscured by a raised, dusky red lesion measuring 1.3 x 0.8 cm. The AV through the pancreatic duct is probe patent. Several attempts to probe the AV with the common bile duct is unsuccessful. The CBD and distal pancreatic margin are submitted for frozen section analysis, the residual frozen tissue submitted en face for permanent sections. The pancreas is initially bisected through the ampulla of Vater, towards the distal margin, revealing a poorly demarcated, dense, pink-gray tumor mass measuring upwards of 3.1 x 3.0 x 2.2 cm, and grossly approaching within 2.8 cm of the distal margin of the pancreas, and 2.8 cm from the common bile duct margin and grossly approaching within 0.5 cm of the pancreatic notch/adventitial margin. The length of the common bile duct is opened, revealing a light pink and tan mucosa that is roughly kinked within the head of the pancreas, and routes parallel to the pancreatic duct and inserts 0.3 cm from the pancreatic duct into the "ampulla of Vater". The tumor mass approaches within 0.5 cm of the edge of the CBD. The tumor is primarily oriented within the head of the pancreas with discrete contiguous relationship with the ampulla of Vater.

In addition, 2.0 cm proximal to the ampulla of Vater, the small bowel demonstrates a distinctly raised, granular area of density, that upon sectioning reveals evidence of an accessory duct with associated firmness suspicious for tumor (C7-C8). The area appears to grossly approach within 0.5 cm of the superior edge of the radial surface, 1.0 cm of the posterior surface, 0.3 cm of the inferior surface, and 0.7 cm of the anterior surface. The surrounding pancreatic parenchyma is admixed fatty and glandular, pink and tan.

No additional lesions are appreciated along the small bowel length, however, the pyloric ridge demonstrates raised granular changes. The gastric mucosa is wrinkled, erythematous light pink and tan, however, abruptly transitions to severely congested, deep red-brown throughout the proximal two-thirds of the gastric antrum. No additional lesions appreciated.

Initial examination of the peripancreatic fat reveals twenty additional lymph nodes ranging from 0.2 cm - 1.4 x 0.8 x 0.8 cm each. Examination of the lesser and greater gastric fat does not reveal gross lymph node content. The lymph nodes are entirely submitted for microscopic evaluation, with the specimen retained in solution to enhance future lymph node, identification if indicated.

Cassette summary:

- C1) distal pancreatic surgical margin, FS,
- C2) CBD margin, FS,
- C3) additional CBD distal end,
- C4) CBD and adjacent tumor relationship,
- C5-C8) AV lesion, parallel CBD and pancreatic duct insertion relationship,
- C7-C8) duodenal lesion, possible fused accessory duct - head of pancreas,
- C9) tumor and pancreatic notch/adventitial margin relationship, possible lymph node,
- C10) additional pancreatic notch margin, two pieces,
- C11) pancreatic tumor, superior edge,
- C12) tumor, posterior edge, including two lymph nodes,
- C13) anterior pancreas, lengthwise sectioned, including distal edge of pancreatic duct, former margin shaved for frozen section,

Case #:

Printed:

Page 3

This report continues... (FINAL)

[page 4 of 4]
FINAL SURGICAL PATHOLOGY REPORT

- C14) inferior pancreas,
- C15) most distal uncinate,
- C16) proximal gastric margin of resection, anterior and posterior,
- C17) distal small bowel margin of resection, trimmed and submitted,
- C18) gastric tissue, including pylorus,
- C19) pylorus and distal length of small bowel,
- C20) small lymph nodes,
- C21) six lymph nodes,
- C22) single lymph node,
- C23) two lymph nodes bisected, one marked orange,
- C24) two lymph nodes bisected, one marked green,
- C25) single lymph node bisected,
- C26) single lymph node bisected,
- C27) single lymph node trisected,
- C28) largest lymph node trisected,
- C29) peripancreatic fat possible lymph node or tumor content, adjacent ink surfaces, four pieces, [REDACTED]

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

An intradepartmental consultation with [REDACTED] was obtained.

[REDACTED] - Page 4

HI/PA Discrepancy		
Case is (c) (2)		

Source: NCI Genomic Data Commons file 40141b54-5940-4ca4-950c-49ffc6960b47 (TCGA-HZ-A77P.71CF594D-2A24-4B98-AF3F-1D97DF421433.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).